TCGA case TCGA-VS-A9UL — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7abaca8f-962e-4f9d-b63f-26c131bf5961

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 79 years; Vital status: Dead; Days to death: 442 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 79.5 years (29,033 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC pathologic T: T3b; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 79 days; Days to treatment end: 118 days; Treatment dose: 4,500 cGy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 119 days; Days to treatment end: 139 days; Treatment dose: 2,800 cGy; Treatment outcome: Progressive Disease; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 124 days; Days to treatment end: 131 days; Treatment dose: 900 cGy; Treatment outcome: Progressive Disease; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,800 cGy; Treatment outcome: Progressive Disease; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 5,400 cGy; Treatment outcome: Progressive Disease; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 80.4 years (29,369 days); Days to diagnosis: 336 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day -1 (prior to adjuvant therapy): ECOG performance status: 1.
- Day 336 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 336 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 442 days (1.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Initial Diagnosis; Weight: 56 kg; Height: 149 cm; BMI: 25.2.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A9UL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 60 mg.
  Slide TCGA-VS-A9UL-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
- Sample TCGA-VS-A9UL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A9UL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 5; Total pregnancy count: 5; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Cause of death: Cervical Cancer.
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 442 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 442 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 336 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A9UL-01A-11D-A42N-01): tumor purity 0.84, ploidy 5.08, whole-genome doublings 2.
